Somatic mutation profile of tumor specimen TARGET-30-PANYBL-01A (aliquot TARGET-30-PANYBL-01A-01W) from TARGET case TARGET-30-PANYBL, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.3 years (1,216 days).
Specimen TARGET-30-PANYBL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47ee9f39-68a7-4d5c-ac42-307b860432f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PANYBL-10A (Blood Derived Normal), aliquot TARGET-30-PANYBL-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47ab5e16-9aeb-48a3-b5df-43d78aa1d023

The open-access MAF lists 37 somatic variants for this specimen: 31 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 26, Silent 6, Nonsense Mutation 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSBG1 | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 10/201 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.092); catalogued as COSV99357693; called by muse, mutect2
- ADGRV1 | c.11929G>T p.A3977S | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV67987679; called by muse, mutect2
- C2CD2 | c.1781G>T p.S594I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.271); catalogued as rs1159817354, COSV61599451; called by muse, mutect2, varscan2
- CFAP54 | c.7828C>A p.L2610I | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV61571396, COSV61571517; called by muse, mutect2
- COL12A1 | c.9129C>A p.Y3043* | Nonsense Mutation (SNP) | VAF 57/280 reads (20%) | catalogued as COSV59395996; called by muse, mutect2, varscan2
- CRYBG3 | c.8533C>T p.R2845C | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1279522626, COSV51711944; called by muse, mutect2, varscan2
- DNAH10 | c.1534G>T p.D512Y (on ENST00000409039; = p.D451Y on NM_207437.3) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV68993768; called by muse, mutect2
- DPP10 | c.250C>A p.P84T | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59686283, COSV59692696; called by muse, mutect2, varscan2
- FBN2 | c.4387G>T p.G1463* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as COSV52512955; called by muse, mutect2, varscan2
- FBXL7 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.088); catalogued as COSV61645946; called by muse, mutect2, varscan2
- FYB2 | c.1851dup p.E618Rfs*6 | Frame Shift Ins (INS) | VAF 17/41 reads (41%) | catalogued as rs751048223; called by mutect2, varscan2
- ICA1 | c.1322C>T p.S441L | Missense Mutation (SNP) | VAF 15/385 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.843); catalogued as rs868309360; called by muse, mutect2
- LRG1 | c.522C>A p.N174K | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56703700; called by muse, mutect2, varscan2
- MC2R | c.331G>T p.V111F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as COSV59618146; called by muse, mutect2, varscan2
- NES | c.4521G>T p.L1507F | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV63961042; called by muse, mutect2, varscan2
- NIM1K | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58141742; called by muse, mutect2, varscan2
- NIPAL1 | c.568C>A p.Q190K | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0.029); catalogued as COSV55006541; called by muse, mutect2, varscan2
- NLRP1 | c.1470C>A p.F490L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); catalogued as COSV52566181, COSV99334742; called by muse, mutect2, varscan2
- NRK | c.1437G>T p.M479I | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV54596614; called by muse, mutect2, varscan2
- PARD3 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV60750094; called by muse, mutect2, varscan2
- PIGC | c.649C>A p.Q217K | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.239); catalogued as COSV51129885, COSV51130821; called by muse, mutect2, varscan2
- SPPL2C | c.1428C>A p.C476* | Nonsense Mutation (SNP) | VAF 16/336 reads (5%) | catalogued as COSV61293082; called by muse, mutect2
- WT1 | c.1439G>C p.R480P | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV60071651; called by muse, varscan2
- ABCC6 | c.2023G>T p.A675S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CUBN | c.3800G>A p.G1267E | Missense Mutation (SNP) | VAF 21/446 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- DCBLD1 | c.1460G>T p.G487V | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); called by muse, mutect2
- MAP3K13 | c.1278G>T p.Q426H | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- MYCBP2 | c.2894C>T p.T965M (on ENST00000357337; = p.T1003M on NM_015057.5) | Missense Mutation (SNP) | VAF 18/443 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2
- NOTCH2 | c.2349C>A p.C783* | Nonsense Mutation (SNP) | VAF 9/177 reads (5%) | called by muse, mutect2
- SLC25A26 | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 10/235 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2
- SLC4A1 | c.1529G>T p.S510I | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CFAP54 | c.5211G>T p.V1737= | Silent (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- CUL7 | c.804C>T p.N268= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as rs752009036, COSV54817026; called by muse, mutect2, varscan2
- HDAC6 | c.3606C>A p.A1202= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV57806795; called by muse, mutect2, varscan2
- HECTD2 | c.912A>G p.P304= | Silent (SNP) | VAF 12/125 reads (10%) | called by muse, mutect2
- OR52W1 | c.663C>A p.G221= | Silent (SNP) | VAF 18/438 reads (4%) | called by muse, mutect2
- TAF1L | c.4080G>T p.L1360= | Silent (SNP) | VAF 26/335 reads (8%) | called by muse, mutect2
